Somatic mutation profile of tumor specimen C3L-02177-01 (aliquot CPT0100530009) from CPTAC case C3L-02177, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 51.5 years (18,822 days).
Specimen C3L-02177-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7166a41a-80d1-4477-8ea7-43bb94ff513f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02177-31 (Blood Derived Normal), aliquot CPT0101970002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c13c1de-5278-4a60-9b28-4d0299bc7a45

The open-access MAF lists 68 somatic variants for this specimen: 44 protein-altering or splice-affecting, 14 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 14, Intron 6, Frame Shift Del 5, Splice Site 4, Splice Region 2, Nonsense Mutation 2, 5'Flank 2, Frame Shift Ins 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.430G>T p.G144* | Nonsense Mutation (SNP) | VAF 249/480 reads (52%) | catalogued as rs869025650, CM058403, CM982008, COSV56544477, COSV56545017; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.7307+1G>A p.X2436_splice | Splice Site (SNP) | VAF 56/213 reads (26%) | catalogued as CS052031, COSV53765309; called by muse, mutect2, varscan2
- ATXN7L3 | c.174G>T p.M58I | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV66989675; called by muse, mutect2, varscan2
- HPR | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 148/556 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1379782150; called by muse, mutect2, varscan2
- ITPR1 | c.7538-8G>A | Splice Region (SNP) | VAF 149/302 reads (49%) | catalogued as rs1283853074; called by muse, mutect2, varscan2
- MYO1F | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 98/339 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as rs1162509781, COSV57795508; called by muse, mutect2, varscan2
- NBAS | c.3254G>A p.R1085Q | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs139422819; called by muse, mutect2
- NR1I3 | c.649T>G p.F217V | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV63467593; called by muse, mutect2, varscan2
- PAPPA | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1023213977; called by muse, mutect2, varscan2
- SIRPB2 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 70/229 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.068); catalogued as rs371415136; called by muse, mutect2, varscan2
- ZNF583 | c.629A>G p.K210R | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs1056066327; called by muse, mutect2, varscan2
- ADGRL1 | c.2863G>A p.V955M (on ENST00000340736 / NM_001008701.3; = p.V950M on NM_014921.5) | Missense Mutation (SNP) | VAF 170/580 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AJUBA | c.1336T>A p.S446T | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- AMBRA1 | c.488G>C p.W163S | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CALHM5 | c.512T>A p.L171Q | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, varscan2
- CCT4 | c.173A>G p.D58G | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DUSP6 | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 87/351 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF3E | c.597+2T>C p.X199_splice | Splice Site (SNP) | VAF 18/108 reads (17%) | called by mutect2, varscan2
- FAM114A1 | c.1333A>C p.M445L | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- FZR1 | c.836_839delinsAT p.W279Yfs*3 | Frame Shift Del (DEL) | VAF 34/133 reads (26%) | called by pindel, varscan2*
- GJA1 | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 129/534 reads (24%) | called by muse, mutect2, varscan2
- HIVEP2 | c.505del p.S169Vfs*36 | Frame Shift Del (DEL) | VAF 58/261 reads (22%) | called by pindel, varscan2
- HSPA1L | c.1745G>T p.W582L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IPO11 | c.2295A>T p.Q765H | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- IQUB | c.157_161dup p.S55Vfs*63 | Frame Shift Ins (INS) | VAF 37/162 reads (23%) | called by mutect2, pindel, varscan2
- KIF13B | c.700C>A p.L234I | Missense Mutation (SNP) | VAF 68/264 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- L3MBTL1 | c.2073G>T p.K691N (on ENST00000418998 / NM_001377303.1; = p.K601N on NM_015478.7) | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.844); called by muse, mutect2
- MAOA | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 148/258 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MED13L | c.6473A>G p.D2158G | Missense Mutation (SNP) | VAF 149/542 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO3B | c.3359A>T p.H1120L | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NACC2 | c.32dup p.N11Kfs*166 | Frame Shift Ins (INS) | VAF 138/515 reads (27%) | called by mutect2, pindel, varscan2
- NLE1 | c.894del p.Y299Mfs*27 | Frame Shift Del (DEL) | VAF 36/172 reads (21%) | called by mutect2, pindel, varscan2
- NYAP2 | c.1304C>A p.T435N | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SDHA | c.1334C>G p.S445W | Missense Mutation (SNP) | VAF 94/372 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- SETD6 | c.1220A>T p.K407M (on ENST00000219315 / NM_001160305.4; = p.K383M on NM_024860.3) | Missense Mutation (SNP) | VAF 107/417 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SFXN4 | c.646T>A p.S216T | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.89); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- SLC7A3 | c.1621-2A>C p.X541_splice | Splice Site (SNP) | VAF 49/94 reads (52%) | called by muse, mutect2, varscan2
- SPIDR | c.2444T>A p.F815Y | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SULT1A2 | c.232del p.R78Gfs*19 | Frame Shift Del (DEL) | VAF 86/340 reads (25%) | called by mutect2, varscan2
- TMA7 | c.160+5G>A | Splice Region (SNP) | VAF 64/192 reads (33%) | called by muse, mutect2, varscan2
- TSC1 | c.2975+1G>A p.X992_splice | Splice Site (SNP) | VAF 154/593 reads (26%) | called by muse, mutect2, varscan2
- ZC3H7A | c.2373del p.F792Lfs*14 | Frame Shift Del (DEL) | VAF 74/382 reads (19%) | called by mutect2, pindel, varscan2
- ZNF653 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.569); called by muse, mutect2
- ZSWIM4 | c.1482C>G p.N494K | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- ACLY | c.1578G>C p.V526= | Silent (SNP) | VAF 8/150 reads (5%) | catalogued as rs782715950; called by muse, mutect2
- BTNL2 | c.1200G>A p.K400= | Silent (SNP) | VAF 50/209 reads (24%) | called by muse, mutect2, varscan2
- DNMT3B | c.1179C>T p.C393= | Silent (SNP) | VAF 128/548 reads (23%) | called by mutect2, varscan2
- ELF1 | c.1242C>T p.S414= | Silent (SNP) | VAF 32/145 reads (22%) | catalogued as rs1414927549, COSV53497412, COSV53501857; called by muse, mutect2
- EPHA10 | c.2682C>G p.S894= | Silent (SNP) | VAF 73/344 reads (21%) | called by muse, mutect2, varscan2
- HIPK2 | c.171C>A p.I57= | Silent (SNP) | VAF 75/272 reads (28%) | called by muse, mutect2, varscan2
- LHX5 | c.459C>G p.P153= | Silent (SNP) | VAF 50/166 reads (30%) | called by muse, mutect2, varscan2
- LIMD2 | c.363C>T p.D121= | Silent (SNP) | VAF 58/203 reads (29%) | catalogued as rs772988770; called by muse, mutect2, varscan2
- MUC16 | c.1149G>A p.K383= | Silent (SNP) | VAF 74/274 reads (27%) | called by muse, mutect2, varscan2
- RAD54L | c.1275G>A p.K425= | Silent (SNP) | VAF 36/740 reads (5%) | catalogued as COSV64336903; called by muse, mutect2
- RNF185 | c.261G>A p.K87= | Silent (SNP) | VAF 43/177 reads (24%) | called by muse, mutect2, varscan2
- SLC2A9 | c.1608A>T p.I536= | Silent (SNP) | VAF 140/491 reads (29%) | called by muse, mutect2, varscan2
- UNC5CL | c.1284T>C p.N428= | Silent (SNP) | VAF 64/256 reads (25%) | called by muse, mutect2, varscan2
- ZNF608 | c.2706G>A p.S902= | Silent (SNP) | VAF 72/252 reads (29%) | catalogued as rs139588123; called by mutect2, varscan2
- C7orf57 | chr7:48035531 C>T | 5'Flank (SNP) | VAF 56/155 reads (36%) | catalogued as rs1051548926; called by muse, mutect2, varscan2
- CD164 | c.370+28T>A | Intron (SNP) | VAF 58/215 reads (27%) | called by muse, mutect2, varscan2
- GPR89A | c.42+329C>T | Intron (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2
- RAG1 | c.*14T>A | 3'UTR (SNP) | VAF 73/284 reads (26%) | called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.81+42C>T | Intron (SNP) | VAF 65/252 reads (26%) | called by muse, mutect2, varscan2
- SLC25A3 | c.645-245del | Intron (DEL) | VAF 85/354 reads (24%) | called by mutect2, pindel, varscan2
- SREBF1 | c.1405-25T>C | Intron (SNP) | VAF 17/94 reads (18%) | called by muse, mutect2, varscan2
- TFAP2A | chr6:10419455 G>A | 5'Flank (SNP) | VAF 52/202 reads (26%) | catalogued as COSV100116430; called by muse, varscan2
- ZNF451 | c.3070+22G>A | Intron (SNP) | VAF 72/213 reads (34%) | catalogued as rs374866664; called by muse, mutect2, varscan2
- ZNF718 | c.-3G>C | 5'UTR (SNP) | VAF 33/173 reads (19%) | called by muse, mutect2, varscan2
